Somatic mutation profile of tumor specimen MMRF_1634_1_BM_CD138pos (aliquot MMRF_1634_1_BM_CD138pos_T2_KHS5U_K14079) from MMRF case MMRF_1634, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 37.0 years (13,510 days).
Specimen MMRF_1634_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 397aba5c-ab0a-40f5-ada6-e322e2eac355.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1634_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1634_1_PB_Whole_C1_KHS5U_K14070; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4fb9857-2f66-4b0a-88bd-08d873a0ee8a

The open-access MAF lists 118 somatic variants for this specimen: 42 protein-altering or splice-affecting, 15 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, 3'UTR 32, Silent 15, Intron 14, 5'UTR 7, 5'Flank 4, 3'Flank 2, RNA 2, Splice Region 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 24/60 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATP7B | c.2695A>C p.I899L | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM076006; called by muse, mutect2, varscan2
- BAG3 | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs748233260, COSV64842026; called by muse, mutect2, varscan2
- BMP6 | c.598C>G p.L200V | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1270040536; called by muse, mutect2, varscan2
- CLIP2 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1554732626; called by muse, mutect2, varscan2
- DDX60 | c.2492G>A p.R831H | Missense Mutation (SNP) | VAF 94/197 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs368004593; called by muse, mutect2, varscan2
- EPB41L4B | c.682G>C p.E228Q | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65797892; called by muse, mutect2, varscan2
- FAT4 | c.6118A>C p.I2040L | Missense Mutation (SNP) | VAF 139/291 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); catalogued as COSV58674332; called by muse, mutect2, varscan2
- FLG | c.8188G>A p.E2730K | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as rs1224614934, COSV100911923; called by mutect2, varscan2
- IGHD6-6 | c.4T>C p.Y2H | Missense Mutation (SNP) | VAF 27/28 reads (96%) | PolyPhen possibly damaging (0.768); catalogued as rs1555399115; called by muse, varscan2
- IGHV1-69D | c.303G>C p.E101D | Missense Mutation (SNP) | VAF 77/156 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.227); catalogued as rs1297658955; called by muse, mutect2, varscan2
- IGHV1-69D | c.161G>C p.S54T | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs1378343210; called by muse, mutect2, varscan2
- KIF27 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as COSV52826334; called by muse, mutect2, varscan2
- KRTAP13-1 | c.224C>A p.P75H | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100819824, COSV62663162; called by muse, mutect2, varscan2
- MICAL2 | c.2998G>A p.D1000N | Missense Mutation (SNP) | VAF 73/147 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs767694414; called by muse, mutect2, varscan2
- NECTIN3 | c.1246A>G p.I416V | Missense Mutation (SNP) | VAF 216/507 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1472777064, COSV60552950; called by muse, mutect2, varscan2
- PKHD1L1 | c.3020T>C p.I1007T | Missense Mutation (SNP) | VAF 92/182 reads (51%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs917618034, COSV65754309; called by muse, mutect2, varscan2
- SI | c.472T>C p.F158L | Missense Mutation (SNP) | VAF 75/146 reads (51%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs1323441269; called by muse, mutect2, varscan2
- ZEB1 | c.736G>C p.G246R | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58049453; called by muse, mutect2, varscan2
- AL645922.1 | c.3290T>G p.I1097S | Missense Mutation (SNP) | VAF 61/121 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APLNR | c.969G>A p.M323I | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASH1L | c.6230T>A p.I2077N (on ENST00000368346 / NM_001366177.2; = p.I2072N on NM_018489.3) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- B3GNTL1 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- BTBD3 | c.456G>T p.M152I | Missense Mutation (SNP) | VAF 69/147 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- CAGE1 | c.962T>C p.V321A (on ENST00000512086; = p.V185A on NM_205864.3) | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP162 | c.3208G>A p.D1070N | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- DLG5 | c.3632C>A p.P1211H | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- ENO3 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 128/241 reads (53%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- EXOC3L4 | c.548G>A p.C183Y | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- GLG1 | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 142/254 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- HSD17B3 | c.672+8G>C | Splice Region (SNP) | VAF 7/182 reads (4%) | called by muse, mutect2
- IGHV2-70D | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.701); called by muse, varscan2
- LAPTM4A | c.94del p.L32Wfs*7 | Frame Shift Del (DEL) | VAF 49/139 reads (35%) | called by mutect2, pindel, varscan2
- LRRC69 | c.183+1G>A p.X61_splice | Splice Site (SNP) | VAF 96/225 reads (43%) | called by muse, mutect2, varscan2
- NLGN4X | c.2015C>A p.S672Y | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.391); called by muse, mutect2
- OTOG | c.2179T>C p.F727L | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2
- P2RY14 | c.388T>A p.S130T | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- RASD1 | c.443A>G p.D148G | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TPCN1 | c.2029-4C>G | Splice Region (SNP) | VAF 36/85 reads (42%) | called by muse, mutect2, varscan2
- TTN | c.52324A>G p.M17442V (on ENST00000591111; = p.M10018V on NM_003319.4) | Missense Mutation (SNP) | VAF 128/288 reads (44%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TXNDC17 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- ULK4 | c.976C>T p.H326Y | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- ACOX3 | c.867C>G p.P289= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as rs749776895; called by muse, mutect2, varscan2
- ADCY9 | c.588G>T p.T196= | Silent (SNP) | VAF 55/113 reads (49%) | catalogued as COSV53573251; called by muse, mutect2, varscan2
- ARHGEF15 | c.1164C>T p.P388= | Silent (SNP) | VAF 57/155 reads (37%) | called by muse, mutect2, varscan2
- CNTN3 | c.2439C>T p.S813= | Silent (SNP) | VAF 79/179 reads (44%) | catalogued as COSV55179008; called by muse, mutect2, varscan2
- DLG5 | c.3633T>C p.P1211= | Silent (SNP) | VAF 36/67 reads (54%) | called by muse, mutect2, varscan2
- IGHD6-6 | c.6T>C p.Y2= | Silent (SNP) | VAF 26/26 reads (100%) | catalogued as rs782640705; called by muse, varscan2
- IGHV2-70 | c.246A>C p.T82= | Silent (SNP) | VAF 62/86 reads (72%) | catalogued as rs367734033; called by muse, varscan2
- IGHV2-70D | c.339G>T p.T113= | Silent (SNP) | VAF 22/35 reads (63%) | catalogued as rs1441146570; called by muse, varscan2
- IGKC | c.75T>G p.V25= | Silent (SNP) | VAF 57/130 reads (44%) | called by muse, mutect2, varscan2
- KLRG2 | c.777G>A p.K259= | Silent (SNP) | VAF 30/85 reads (35%) | called by muse, mutect2, varscan2
- MTARC2 | c.585C>T p.L195= | Silent (SNP) | VAF 111/189 reads (59%) | called by muse, mutect2, varscan2
- PLA2G2F | c.174G>A p.L58= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV100907925; called by muse, mutect2, varscan2
- PRKG1 | c.561T>C p.L187= | Silent (SNP) | VAF 76/199 reads (38%) | called by muse, mutect2, varscan2
- TMEM131 | c.135G>A p.A45= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs754819865; called by muse, varscan2
- VSIG10L | c.2295C>T p.V765= | Silent (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- ABCC13 | n.3742G>T | RNA (SNP) | VAF 10/230 reads (4%) | called by muse, mutect2
- ABRAXAS1 | c.682-171C>T | Intron (SNP) | VAF 5/10 reads (50%) | called by muse, varscan2
- AC073310.1 | n.404C>T | RNA (SNP) | VAF 55/70 reads (79%) | called by muse, mutect2, varscan2
- ACHE | chr7:100896940 C>T | 5'Flank (SNP) | VAF 7/16 reads (44%) | catalogued as rs996490338; called by muse, mutect2, varscan2
- ACYP1 | c.84+1734T>C | Intron (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2
- AGBL4 | c.1267+2599A>C | Intron (SNP) | VAF 43/91 reads (47%) | called by muse, mutect2, varscan2
- AGO1 | c.*1468T>C | 3'UTR (SNP) | VAF 59/133 reads (44%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846083 C>T | 5'Flank (SNP) | VAF 60/72 reads (83%) | catalogued as rs758496689; called by muse, mutect2, varscan2
- ARHGEF10L | c.*453G>A | 3'UTR (SNP) | VAF 79/214 reads (37%) | called by muse, mutect2, varscan2
- ARID2 | c.5363+42T>C | Intron (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- ARSD | c.*807C>T | 3'UTR (SNP) | VAF 13/109 reads (12%) | catalogued as rs752452203; called by muse, mutect2, varscan2
- CCDC38 | c.37+3280A>T | Intron (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- CCDC93 | c.*1436T>G | 3'UTR (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- CCT6A | c.1450+180G>A | Intron (SNP) | VAF 34/52 reads (65%) | called by muse, mutect2, varscan2
- CLIP2 | c.*1954G>T | 3'UTR (SNP) | VAF 126/310 reads (41%) | called by muse, mutect2, varscan2
- CUBN | c.4696-11359A>C | Intron (SNP) | VAF 74/135 reads (55%) | called by muse, mutect2, varscan2
- DCK | c.*547T>C | 3'UTR (SNP) | VAF 34/99 reads (34%) | called by muse, varscan2
- DLG4 | c.-289G>T | 5'UTR (SNP) | VAF 6/15 reads (40%) | called by muse, varscan2
- DST | chr6:56458887 C>T | 3'Flank (SNP) | VAF 64/129 reads (50%) | called by muse, mutect2, varscan2
- EPB41L4A | chr5:112160992 G>C | 3'Flank (SNP) | VAF 11/144 reads (8%) | called by muse, mutect2
- EYA3 | c.*731T>A | 3'UTR (SNP) | VAF 24/89 reads (27%) | called by muse, mutect2, varscan2
- GALNT17 | c.239-27855T>G | Intron (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- GRAMD2B | c.128+11058C>T | Intron (SNP) | VAF 8/140 reads (6%) | catalogued as rs958765595; called by muse, mutect2
- HGF | c.*3041C>A | 3'UTR (SNP) | VAF 15/25 reads (60%) | called by muse, mutect2, varscan2
- HYAL1 | c.*208C>A | 3'UTR (SNP) | VAF 62/121 reads (51%) | called by muse, mutect2, varscan2
- IGHV1-69 | c.-39C>T | 5'UTR (SNP) | VAF 19/40 reads (48%) | catalogued as rs782323083; called by muse, varscan2
- IGLL5 | c.-40C>T | 5'UTR (SNP) | VAF 39/77 reads (51%) | catalogued as rs145696836, COSV73251009; called by muse, mutect2, varscan2
- LARP1B | c.*1056T>A | 3'UTR (SNP) | VAF 13/17 reads (76%) | called by muse, mutect2, varscan2
- MDH1B | c.*254T>A | 3'UTR (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- MINDY2 | c.*4511_*4514del | 3'UTR (DEL) | VAF 34/76 reads (45%) | called by mutect2, pindel, varscan2
- MINDY3 | c.*573C>T | 3'UTR (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- MOSMO | chr16:22007707 C>G | 5'Flank (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- MYC | c.-395A>G | 5'UTR (SNP) | VAF 12/112 reads (11%) | catalogued as COSV104388180; called by muse, mutect2, varscan2
- NOP56 | c.208+97T>G | Intron (SNP) | VAF 22/40 reads (55%) | called by muse, mutect2
- NTRK3 | c.*11013T>C | 3'UTR (SNP) | VAF 39/92 reads (42%) | called by muse, mutect2, varscan2
- PASD1 | c.*349del | 3'UTR (DEL) | VAF 74/78 reads (95%) | called by mutect2, pindel*, varscan2
- PCMTD2 | c.*584T>G | 3'UTR (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2, varscan2
- PML | c.*726C>G | 3'UTR (SNP) | VAF 87/191 reads (46%) | called by muse, mutect2, varscan2
- PPEF2 | c.*96G>C | 3'UTR (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- PREX2 | c.*2679C>T | 3'UTR (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
- PSG11 | c.964+648C>T | Intron (SNP) | VAF 29/72 reads (40%) | catalogued as rs1171091180; called by muse, mutect2, varscan2
- PTCH1 | c.202-81_202-80insAGGCGGGTGCGCGCAAGC | Intron (INS) | VAF 5/8 reads (63%) | called by muse*, mutect2, varscan2*
- PTGER2 | c.*431C>T | 3'UTR (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- PVRIG | chr7:100218466 G>A | 5'Flank (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- RCHY1 | c.*513A>G | 3'UTR (SNP) | VAF 40/82 reads (49%) | catalogued as rs1019597971; called by muse, mutect2
- REM1 | c.-158C>T | 5'UTR (SNP) | VAF 11/116 reads (9%) | called by muse, mutect2
- RIMKLB | c.*3324T>C | 3'UTR (SNP) | VAF 18/31 reads (58%) | called by muse, mutect2, varscan2
- SEC22C | c.*2986G>A | 3'UTR (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- SHH | c.301-238C>A | Intron (SNP) | VAF 9/115 reads (8%) | called by muse, mutect2
- SHISA9 | c.563+6204C>T | Intron (SNP) | VAF 52/102 reads (51%) | called by muse, mutect2, varscan2
- SHQ1 | c.*917T>A | 3'UTR (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- TCTEX1D1 | c.*1360del | 3'UTR (DEL) | VAF 12/34 reads (35%) | catalogued as rs1002496282; called by mutect2, varscan2
- TGFB2 | c.*522A>C | 3'UTR (SNP) | VAF 88/132 reads (67%) | called by muse, mutect2, varscan2
- TMEM183A | c.*502C>T | 3'UTR (SNP) | VAF 67/131 reads (51%) | called by muse, mutect2, varscan2
- TMEM268 | c.*2630T>A | 3'UTR (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- TRA2A | c.-81T>C | 5'UTR (SNP) | VAF 70/136 reads (51%) | called by muse, varscan2
- TRA2A | c.-147A>C | 5'UTR (SNP) | VAF 70/144 reads (49%) | called by muse, varscan2
- TSC22D2 | c.*1293A>G | 3'UTR (SNP) | VAF 28/58 reads (48%) | called by muse, mutect2, varscan2
- TTN | c.*432G>A | 3'UTR (SNP) | VAF 9/78 reads (12%) | catalogued as rs1305793357; called by muse, mutect2, varscan2
- UBE2K | c.*1318A>T | 3'UTR (SNP) | VAF 33/52 reads (63%) | called by muse, mutect2, varscan2
- ZC3H6 | c.*5997del | 3'UTR (DEL) | VAF 12/112 reads (11%) | called by mutect2, pindel
